Somatic mutation profile of tumor specimen TCGA-06-0128-01A (aliquot TCGA-06-0128-01A-01D-1490-08) from TCGA case TCGA-06-0128, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,217 days).
Specimen TCGA-06-0128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4471b40f-cb1e-4abe-be3d-d59340ff3fed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0128-10A (Blood Derived Normal), aliquot TCGA-06-0128-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/884d91e4-587c-404b-8464-5ff48cf943ec

The open-access MAF lists 57 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 35, Silent 9, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 64/154 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC5 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.241); catalogued as rs201560541, COSV55593149; called by muse, mutect2, varscan2
- ADAM29 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.183); catalogued as rs148389603; called by muse, mutect2, varscan2
- ARMC5 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV51658099; called by muse, mutect2, varscan2
- BCAM | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV54303422; called by muse, mutect2
- BCS1L | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs779892991, COSV55308415; called by muse, mutect2
- C3 | c.2090G>A p.G697D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55576225; called by muse, mutect2
- CHODL | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV53043243; called by muse, mutect2
- EVPL | c.5191C>T p.P1731S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV56913202; called by muse, mutect2, varscan2
- FGD5 | c.1511A>G p.E504G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53246847; called by muse, mutect2
- FPR1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100494020; called by muse, mutect2
- G2E3 | c.1560C>G p.Y520* | Nonsense Mutation (SNP) | VAF 32/221 reads (14%) | catalogued as COSV52841553; called by muse, mutect2, varscan2
- GGA1 | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs913218146, COSV57330800; called by muse, mutect2, varscan2
- HOXA2 | c.89A>T p.D30V | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56067098; called by muse, mutect2, varscan2
- IL16 | c.2807dup p.G937Wfs*14 (on ENST00000302987 / NM_172217.5; = p.G236Wfs*14 on NM_004513.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/85 reads (38%) | catalogued as rs1442868485; called by mutect2, pindel, varscan2
- KALRN | c.8936T>C p.V2979A (on ENST00000360013 / NM_001024660.4; = p.V1282A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.009); catalogued as COSV52260290; called by muse, mutect2
- KDR | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55769901, COSV55770416; called by muse, mutect2
- LINGO2 | c.1227dup p.P410Tfs*5 | Frame Shift Ins (INS) | VAF 18/182 reads (10%) | catalogued as rs1358205090; called by mutect2, pindel
- MFRP | c.509A>C p.E170A (on ENST00000449574; = p.E546A on NM_031433.4) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773902427, COSV60990961; called by muse, mutect2, varscan2
- MS4A14 | c.135G>T p.L45F | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55730729; called by muse, mutect2, varscan2
- MYO18B | c.4634C>T p.S1545L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); catalogued as rs537916951, COSV59138298; called by muse, mutect2, varscan2
- NCKAP1 | c.649A>G p.R217G | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62942074; called by muse, mutect2, varscan2
- PAN3 | c.2050-2A>G p.X684_splice | Splice Site (SNP) | VAF 13/86 reads (15%) | catalogued as COSV56705047; called by muse, mutect2, varscan2
- PCDHA8 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV65324151; called by muse, mutect2, varscan2
- PPIL6 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 14/160 reads (9%) | catalogued as COSV70022376; called by muse, mutect2
- PPP1R3A | c.1862G>T p.R621I | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV52885310, COSV52886773; called by muse, mutect2, varscan2
- RRP8 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV54450175; called by muse, mutect2, varscan2
- SACS | c.5584A>G p.T1862A | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV66535653; called by muse, mutect2, varscan2
- SF3A1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 22/179 reads (12%) | catalogued as COSV53169990; called by muse, mutect2, varscan2
- SLC3A1 | c.1104G>C p.M368I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as COSV53223628; called by muse, mutect2, varscan2
- SLC45A1 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57097566; called by muse, mutect2, varscan2
- SLC45A3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772584733, COSV65655151; called by muse, mutect2, varscan2
- SLIT2 | c.2324A>G p.N775S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV56581817; called by muse, mutect2, varscan2
- SPNS3 | c.110G>A p.W37* | Nonsense Mutation (SNP) | VAF 57/138 reads (41%) | catalogued as COSV100337025, COSV61069179; called by muse, mutect2, varscan2
- SSTR5 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV53512751; called by muse, mutect2, varscan2
- TCF12 | c.1511-1G>C p.X504_splice | Splice Site (SNP) | VAF 22/59 reads (37%) | catalogued as COSV51012285; called by muse, mutect2, varscan2
- THADA | c.870T>A p.F290L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV57687849; called by muse, mutect2
- TMPRSS11A | c.856A>C p.T286P | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV58359642; called by muse, mutect2, varscan2
- TP53 | c.936del p.S313Afs*32 | Frame Shift Del (DEL) | VAF 117/191 reads (61%) | catalogued as CD165594, COSV52772076, COSV53210453; called by mutect2, pindel, varscan2
- TPCN2 | c.249A>G p.Q83= | Splice Region (SNP) | VAF 15/60 reads (25%) | catalogued as rs142314553; called by muse, mutect2, varscan2
- TUSC3 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 131/336 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV101141249, COSV65884171; called by muse, mutect2, varscan2
- WDHD1 | c.1836A>C p.Q612H | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV62214775; called by muse, mutect2, varscan2
- WDR43 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs376467674; called by muse, mutect2, varscan2
- ZNF440 | c.1182A>C p.K394N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100407560, COSV58371734; called by muse, mutect2
- ZNF586 | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV66972515; called by muse, mutect2, varscan2
- GPBAR1 | c.962_965del p.S321Kfs*8 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- KRT34 | c.20del p.P7Hfs*7 | Frame Shift Del (DEL) | VAF 25/132 reads (19%) | called by mutect2, pindel, varscan2
- TCF12 | c.1418_1419del p.S473Cfs*12 | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | called by pindel, varscan2
- ACVR1 | c.699C>T p.A233= | Silent (SNP) | VAF 100/219 reads (46%) | catalogued as rs182542928, COSV55120452; called by muse, mutect2, varscan2
- C16orf91 | c.189G>A p.S63= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs1281098278, COSV100113689, COSV59950465; called by muse, mutect2, varscan2
- EXO1 | c.2388A>G p.K796= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV62218386; called by muse, mutect2, varscan2
- HBZ | c.66C>T p.A22= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs368733826, COSV53316886; called by muse, mutect2, varscan2
- MAGI2 | c.2457T>A p.L819= | Silent (SNP) | VAF 66/204 reads (32%) | catalogued as COSV62678568; called by muse, mutect2, varscan2
- PDE3A | c.2115A>G p.R705= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV62977108, COSV62977279; called by muse, mutect2, varscan2
- PDILT | c.1632C>T p.Y544= | Silent (SNP) | VAF 169/437 reads (39%) | catalogued as rs374255958, COSV56701088; called by muse, mutect2, varscan2
- TRIM32 | c.1578C>T p.T526= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs778620127, COSV57795149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF644 | c.1740C>G p.S580= | Silent (SNP) | VAF 143/390 reads (37%) | catalogued as COSV61348830; called by muse, mutect2, varscan2
